Somatic mutation profile of tumor specimen ALCH-B1MR-TTP1-A (aliquot ALCH-B1MR-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1MR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 78.6 years (28,721 days).
Specimen ALCH-B1MR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4845504-0b51-4621-9945-83901e52c93e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1MR-NB1-A (Blood Derived Normal), aliquot ALCH-B1MR-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b870abbe-e9df-40b6-8d16-3b8f49733c14

The open-access MAF lists 164 somatic variants for this specimen: 101 protein-altering or splice-affecting, 46 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 46, Intron 10, Nonsense Mutation 3, 5'UTR 2, RNA 2, 3'UTR 1, 5'Flank 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 24/417 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52660939, COSV52789715, COSV53470581; called by muse, mutect2
- ACOT1 | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 35/590 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100233469; called by muse, mutect2
- ANKRD18B | c.1577G>T p.R526L | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV52095959; called by muse, mutect2, varscan2
- ANKRD30A | c.1077G>T p.R359S (on ENST00000611781; = p.R303S on NM_052997.2) | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.775); catalogued as COSV64615315; called by muse, mutect2
- APOE | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 36/374 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.703); catalogued as rs757764781, COSV52985043; called by muse, mutect2
- ASZ1 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV52911316; called by muse, mutect2
- ATRNL1 | c.3833C>T p.P1278L | Missense Mutation (SNP) | VAF 51/636 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs781954124; called by muse, mutect2
- BMF | c.461A>C p.Q154P | Missense Mutation (SNP) | VAF 42/468 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as rs772116970; called by muse, mutect2
- C1orf141 | c.957G>T p.Q319H | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV63992007; called by muse, mutect2
- CFHR5 | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 17/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201808624, COSV99888045; called by muse, mutect2
- CTNND2 | c.1279C>A p.R427S | Missense Mutation (SNP) | VAF 36/702 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773745550, COSV58868584; called by muse, mutect2
- FAM47C | c.1516C>T p.R506C | Missense Mutation (SNP) | VAF 40/523 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.093); catalogued as rs370557345, COSV63728974, COSV63729626; called by muse, mutect2
- FBN2 | c.8140G>A p.E2714K | Missense Mutation (SNP) | VAF 38/656 reads (6%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.578); catalogued as rs766619186, COSV52544134; called by muse, mutect2
- FNDC1 | c.1355T>A p.V452D | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51949354; called by muse, mutect2
- GABRA5 | c.1001C>A p.A334E | Missense Mutation (SNP) | VAF 53/956 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59485712; called by muse, mutect2
- GALNT17 | c.1222G>T p.D408Y | Missense Mutation (SNP) | VAF 50/517 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV61149532, COSV61173595; called by muse, mutect2, varscan2
- GATA3 | c.284C>G p.P95R | Missense Mutation (SNP) | VAF 46/476 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV60515721, COSV60517953; called by muse, mutect2
- KCNV1 | c.1324G>T p.E442* | Nonsense Mutation (SNP) | VAF 26/404 reads (6%) | catalogued as COSV52084745; called by muse, mutect2
- KCNV1 | c.1323G>T p.K441N | Missense Mutation (SNP) | VAF 27/407 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV52084956, COSV52085634; called by muse, mutect2
- KCNV1 | c.341T>G p.L114R | Missense Mutation (SNP) | VAF 56/1047 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV52085677; called by muse, mutect2
- KIF13A | c.4792G>T p.G1598C | Missense Mutation (SNP) | VAF 19/224 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99438417; called by muse, mutect2
- KIF13A | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 10/273 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52447427; called by muse, mutect2
- LOXHD1 | c.3566C>A p.A1189E | Missense Mutation (SNP) | VAF 32/495 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56060222, COSV56061194; called by muse, mutect2
- NT5C1A | c.61A>G p.T21A | Missense Mutation (SNP) | VAF 32/480 reads (7%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs770933231, COSV52494785; called by muse, mutect2
- OR4C3 | c.634C>A p.L212M | Missense Mutation (SNP) | VAF 12/382 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1363629237; called by muse, mutect2
- OR8G1 | c.192C>G p.S64R | Missense Mutation (SNP) | VAF 24/556 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.043); catalogued as COSV58383670; called by muse, mutect2
- PRRC2B | c.1806C>A p.N602K | Missense Mutation (SNP) | VAF 18/564 reads (3%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs1421756958; called by muse, mutect2
- PUS1 | c.342T>G p.D114E | Missense Mutation (SNP) | VAF 55/689 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.124); catalogued as rs750814179; called by muse, mutect2
- RICTOR | c.4810G>T p.D1604Y | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57123204; called by muse, mutect2, varscan2
- SAGE1 | c.1958G>T p.R653L | Missense Mutation (SNP) | VAF 30/217 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.176); catalogued as COSV61014370; called by muse, mutect2, varscan2
- SCAF1 | c.2021C>T p.S674L | Missense Mutation (SNP) | VAF 8/175 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs1426617965, COSV62182992; called by muse, mutect2
- SEMA6D | c.2257G>T p.D753Y (on ENST00000316364 / NM_153618.2; = p.D691Y on NM_020858.2) | Missense Mutation (SNP) | VAF 18/358 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV60375483; called by muse, mutect2
- SI | c.3622C>G p.Q1208E | Missense Mutation (SNP) | VAF 26/430 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.364); catalogued as COSV100015032; called by muse, mutect2
- SLC7A3 | c.1084G>T p.A362S | Missense Mutation (SNP) | VAF 37/274 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.307); catalogued as COSV53228815, COSV53229643; called by muse, mutect2, varscan2
- SPTBN1 | c.6295C>T p.R2099W | Missense Mutation (SNP) | VAF 96/852 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs778160145, COSV61694270; called by muse, mutect2, varscan2
- TTN | c.79966G>C p.G26656R (on ENST00000591111; = p.G19232R on NM_003319.4) | Missense Mutation (SNP) | VAF 22/282 reads (8%) | PolyPhen possibly damaging (0.88); catalogued as COSV59933790; called by muse, mutect2
- TTN | c.25528C>T p.L8510F (on ENST00000591111; = p.L7583F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/70 reads (10%) | PolyPhen probably damaging (0.96); catalogued as COSV60114865; called by mutect2, varscan2
- UBE2QL1 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 26/409 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.747); catalogued as rs1430240147, COSV67715952; called by muse, mutect2
- ZFP42 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 19/231 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58816567; called by muse, mutect2
- ACSS3 | c.1996-2A>T p.X666_splice | Splice Site (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- ADGRG5 | c.928C>A p.P310T | Missense Mutation (SNP) | VAF 56/968 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.575); called by muse, mutect2
- ANKRD61 | c.1108T>C p.S370P | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- C5orf51 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 35/342 reads (10%) | called by muse, mutect2, varscan2
- CARMIL1 | c.274A>T p.S92C | Missense Mutation (SNP) | VAF 25/333 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.376); called by muse, mutect2
- CLEC11A | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 28/339 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); called by muse, mutect2
- CLIP1 | c.2020A>G p.I674V (on ENST00000620786 / NM_001247997.1; = p.I663V on NM_002956.2) | Missense Mutation (SNP) | VAF 18/405 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.024); called by muse, mutect2
- CUBN | c.5391G>T p.E1797D | Missense Mutation (SNP) | VAF 36/460 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- DGKI | c.213C>A p.S71R | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); called by muse, varscan2
- EFCC1 | c.392T>C p.L131P | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); called by muse, mutect2
- ESR1 | c.557C>A p.A186E | Missense Mutation (SNP) | VAF 29/509 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- FMN1 | c.13C>T p.H5Y | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- KALRN | c.1601A>T p.Q534L | Missense Mutation (SNP) | VAF 31/426 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- KMT2D | c.9608G>C p.G3203A | Missense Mutation (SNP) | VAF 23/235 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.031); called by muse, mutect2
- KRT78 | c.130T>A p.F44I | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.086); called by muse, mutect2
- LRRK2 | c.4340T>C p.V1447A | Missense Mutation (SNP) | VAF 23/715 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MAEA | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 26/461 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- MAST3 | c.1286G>T p.S429I | Missense Mutation (SNP) | VAF 56/986 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.392); called by muse, mutect2
- MYH1 | c.5552T>C p.V1851A | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.073); called by muse, mutect2
- NBPF12 | c.1462C>G p.P488A | Missense Mutation (SNP) | VAF 45/1434 reads (3%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.932); called by muse, mutect2
- NEIL3 | c.736T>C p.Y246H | Missense Mutation (SNP) | VAF 24/297 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2
- NPAP1 | c.1576C>G p.P526A | Missense Mutation (SNP) | VAF 19/529 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.05); called by muse, mutect2
- NUP205 | c.2834A>T p.Q945L | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.022); called by muse, mutect2
- NUP210 | c.1660G>C p.E554Q | Missense Mutation (SNP) | VAF 27/333 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.522); called by muse, mutect2
- OR10K1 | c.607G>T p.G203C | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.02); called by muse, mutect2
- PAPPA | c.1727G>T p.G576V | Missense Mutation (SNP) | VAF 62/710 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PELI3 | c.482T>C p.I161T | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PPDPFL | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 18/418 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.302); called by muse, mutect2
- PRR30 | c.235A>T p.N79Y | Missense Mutation (SNP) | VAF 32/620 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.407); called by muse, mutect2
- RANBP10 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 48/562 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- RPE65 | c.134G>A p.C45Y | Missense Mutation (SNP) | VAF 57/958 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); called by muse, mutect2
- SAA2 | c.317G>A p.S106N | Missense Mutation (SNP) | VAF 21/627 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.105); called by muse, mutect2
- SAMSN1 | c.194G>A p.G65D | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.243); called by muse, mutect2
- SELENON | c.1193T>G p.F398C | Missense Mutation (SNP) | VAF 42/588 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SH2B3 | c.1088C>G p.P363R | Missense Mutation (SNP) | VAF 80/1392 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SHANK1 | c.907A>T p.N303Y | Missense Mutation (SNP) | VAF 51/836 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.761); called by muse, mutect2
- SOX14 | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 11/309 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.315); called by muse, mutect2
- SPATA48 | c.434C>A p.P145Q | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); called by muse, mutect2
- SPATC1 | c.430C>G p.P144A | Missense Mutation (SNP) | VAF 32/756 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.196); called by muse, mutect2
- SPTA1 | c.994C>A p.L332I | Missense Mutation (SNP) | VAF 34/658 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- SPTA1 | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 42/742 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- SPTBN5 | c.7095G>C p.E2365D | Missense Mutation (SNP) | VAF 40/528 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2
- STRC | c.4087A>G p.T1363A | Missense Mutation (SNP) | VAF 96/1876 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0.011); called by muse, mutect2
- SYNE1 | c.5680A>G p.T1894A (on ENST00000367255 / NM_182961.4; = p.T1901A on NM_033071.3) | Missense Mutation (SNP) | VAF 48/940 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2
- TBC1D10C | c.1228C>A p.Q410K | Missense Mutation (SNP) | VAF 34/440 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.117); called by muse, mutect2
- TBC1D2B | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 40/428 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2
- TMEM184C | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 21/246 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.023); called by muse, mutect2
- TRIM66 | c.605A>G p.Q202R | Missense Mutation (SNP) | VAF 20/514 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- TRPM5 | c.2886C>A p.F962L | Missense Mutation (SNP) | VAF 27/667 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- TSHZ2 | c.121C>A p.Q41K | Missense Mutation (SNP) | VAF 50/403 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- UBAP1L | c.769C>T p.H257Y | Missense Mutation (SNP) | VAF 21/339 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2
- UBXN4 | c.1145A>G p.D382G | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2
- UNC80 | c.4555G>T p.V1519L | Missense Mutation (SNP) | VAF 22/602 reads (4%) | SIFT tolerated (0.74); PolyPhen benign (0.014); called by muse, mutect2
- VGLL2 | c.328C>A p.P110T | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.049); called by muse, mutect2
- VSIG10L | c.520G>T p.A174S | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, mutect2
- ZBTB2 | c.1286G>T p.C429F | Missense Mutation (SNP) | VAF 32/624 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2
- ZFAND3 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZFHX4 | c.4505T>C p.V1502A | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- ZNF208 | c.3545C>G p.S1182* | Nonsense Mutation (SNP) | VAF 20/269 reads (7%) | called by muse, mutect2
- ZNF335 | c.887A>T p.E296V | Missense Mutation (SNP) | VAF 69/513 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- ZNF577 | c.109T>C p.W37R | Missense Mutation (SNP) | VAF 15/413 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF628 | c.1673A>T p.H558L | Missense Mutation (SNP) | VAF 25/409 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.35); called by muse, mutect2
- ABCC8 | c.234C>A p.T78= | Silent (SNP) | VAF 45/969 reads (5%) | called by muse, mutect2
- BACH1 | c.2127T>A p.A709= | Silent (SNP) | VAF 12/298 reads (4%) | catalogued as COSV54517959; called by muse, mutect2
- BSG | c.606C>T p.S202= | Silent (SNP) | VAF 22/442 reads (5%) | catalogued as rs969288382; called by muse, mutect2
- CCDC3 | c.498G>A p.G166= | Silent (SNP) | VAF 16/241 reads (7%) | called by muse, mutect2
- CD109 | c.3589C>T p.L1197= | Silent (SNP) | VAF 12/284 reads (4%) | called by muse, mutect2
- CD4 | c.480T>C p.G160= | Silent (SNP) | VAF 11/314 reads (4%) | called by muse, mutect2
- CEP164 | c.2937G>A p.Q979= | Silent (SNP) | VAF 16/222 reads (7%) | called by muse, mutect2
- COL4A4 | c.1725G>T p.G575= | Silent (SNP) | VAF 25/535 reads (5%) | catalogued as COSV61635662; called by muse, mutect2
- DHX34 | c.537G>A p.Q179= | Silent (SNP) | VAF 38/386 reads (10%) | called by muse, mutect2
- DSG2 | c.1446T>A p.T482= | Silent (SNP) | VAF 41/367 reads (11%) | called by muse, mutect2, varscan2
- F5 | c.3087A>T p.T1029= | Silent (SNP) | VAF 35/606 reads (6%) | called by muse, mutect2
- FBL | c.927C>A p.V309= | Silent (SNP) | VAF 28/436 reads (6%) | catalogued as COSV55682308; called by muse, mutect2
- FNIP2 | c.840T>C p.N280= | Silent (SNP) | VAF 34/297 reads (11%) | called by muse, mutect2, varscan2
- FOXJ2 | c.93C>T p.S31= | Silent (SNP) | VAF 54/607 reads (9%) | called by muse, mutect2
- GCC2 | c.4755C>G p.T1585= | Silent (SNP) | VAF 62/869 reads (7%) | called by muse, mutect2
- GEN1 | c.1527G>T p.S509= | Silent (SNP) | VAF 7/134 reads (5%) | called by muse, mutect2
- GYS2 | c.1140G>T p.L380= | Silent (SNP) | VAF 40/413 reads (10%) | called by muse, mutect2
- IFNAR2 | c.837C>T p.V279= | Silent (SNP) | VAF 9/93 reads (10%) | called by muse, mutect2, varscan2
- KCNA6 | c.1335T>C p.A445= | Silent (SNP) | VAF 14/188 reads (7%) | catalogued as rs751823974; called by muse, mutect2
- KDM5C | c.1605T>C p.Y535= | Silent (SNP) | VAF 36/460 reads (8%) | called by muse, mutect2
- LDHAL6B | c.222C>A p.I74= | Silent (SNP) | VAF 106/921 reads (12%) | called by muse, mutect2, varscan2
- MARCKS | c.120G>A p.K40= | Silent (SNP) | VAF 21/353 reads (6%) | catalogued as rs988619790; called by muse, mutect2
- MTOR | c.4428G>A p.L1476= | Silent (SNP) | VAF 23/277 reads (8%) | called by muse, mutect2
- NLRP12 | c.582C>T p.I194= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV60744598; called by muse, mutect2
- NOC4L | c.1215G>T p.V405= | Silent (SNP) | VAF 18/168 reads (11%) | called by muse, mutect2, varscan2
- OR11A1 | c.153G>T p.V51= | Silent (SNP) | VAF 20/324 reads (6%) | called by muse, mutect2
- PCDHA6 | c.1671C>T p.D557= | Silent (SNP) | VAF 60/1422 reads (4%) | catalogued as COSV65341441; called by muse, mutect2
- PHKB | c.2830C>A p.R944= | Silent (SNP) | VAF 45/904 reads (5%) | catalogued as COSV100067617; called by muse, mutect2
- PLCG1 | c.1056C>G p.A352= | Silent (SNP) | VAF 40/777 reads (5%) | catalogued as COSV54819714; called by muse, mutect2
- PLEKHM1 | c.1038C>G p.T346= | Silent (SNP) | VAF 46/702 reads (7%) | called by muse, mutect2
- PNLIPRP3 | c.243A>G p.S81= | Silent (SNP) | VAF 32/238 reads (13%) | catalogued as rs1226826152; called by muse, varscan2
- PRDM14 | c.240G>T p.P80= | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as rs1216284463, COSV99399871; called by muse, mutect2
- PTGER3 | c.540C>T p.G180= | Silent (SNP) | VAF 9/163 reads (6%) | called by muse, mutect2
- PUS10 | c.249A>T p.L83= | Silent (SNP) | VAF 32/179 reads (18%) | called by muse, mutect2, varscan2
- SDC4 | c.9C>T p.P3= | Silent (SNP) | VAF 54/321 reads (17%) | catalogued as rs893497856; called by muse, mutect2, varscan2
- SINHCAF | c.57C>T p.C19= | Silent (SNP) | VAF 30/442 reads (7%) | called by muse, mutect2
- SLC30A9 | c.678C>T p.S226= | Silent (SNP) | VAF 17/278 reads (6%) | catalogued as COSV52559733; called by muse, mutect2
- SLC4A8 | c.2055C>T p.G685= | Silent (SNP) | VAF 16/438 reads (4%) | called by muse, mutect2
- SPTA1 | c.621G>A p.L207= | Silent (SNP) | VAF 50/1018 reads (5%) | called by muse, mutect2
- STARD9 | c.3993A>T p.P1331= | Silent (SNP) | VAF 30/338 reads (9%) | called by muse, mutect2
- TENM4 | c.1998A>G p.T666= | Silent (SNP) | VAF 58/781 reads (7%) | catalogued as rs373948141; called by muse, mutect2
- TTN | c.951C>A p.P317= | Silent (SNP) | VAF 14/442 reads (3%) | called by muse, mutect2
- UNC45A | c.2643G>T p.R881= | Silent (SNP) | VAF 48/790 reads (6%) | called by muse, mutect2
- ZFHX4 | c.3561C>G p.T1187= | Silent (SNP) | VAF 28/336 reads (8%) | called by muse, mutect2
- ZNF808 | c.1080C>A p.R360= | Silent (SNP) | VAF 18/195 reads (9%) | called by muse, mutect2
- ZNF891 | c.249A>G p.E83= | Silent (SNP) | VAF 6/73 reads (8%) | called by muse, mutect2
- ACER3 | c.267+95G>A | Intron (SNP) | VAF 8/87 reads (9%) | called by muse, mutect2
- CCDC180 | c.3903-17C>A | Intron (SNP) | VAF 13/189 reads (7%) | called by muse, mutect2
- EIF2B5 | c.1180+16G>A | Intron (SNP) | VAF 34/592 reads (6%) | catalogued as rs1292395599; called by muse, mutect2
- FUT10 | c.82-2265A>G | Intron (SNP) | VAF 10/162 reads (6%) | catalogued as rs1393046543; called by muse, mutect2
- KCTD17 | c.211-490C>G | Intron (SNP) | VAF 60/658 reads (9%) | called by muse, mutect2
- LINC00602 | n.849G>A | RNA (SNP) | VAF 14/238 reads (6%) | called by muse, mutect2
- MED24 | c.1531-17C>G | Intron (SNP) | VAF 24/534 reads (4%) | called by muse, mutect2
- MYOZ2 | c.*46C>A | 3'UTR (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- NLRP7 | c.2810+2774C>T | Intron (SNP) | VAF 42/515 reads (8%) | catalogued as rs1488877944; called by muse, mutect2
- POLR1H | chr6:30057192 G>A | 5'Flank (SNP) | VAF 18/367 reads (5%) | called by muse, mutect2
- POU3F4 | c.-18A>G | 5'UTR (SNP) | VAF 52/467 reads (11%) | catalogued as rs1487554797; called by muse, mutect2, varscan2
- PRDM11 | chr11:45227939 G>T | 3'Flank (SNP) | VAF 15/298 reads (5%) | called by muse, mutect2
- PYGL | c.2379+42A>G | Intron (SNP) | VAF 16/206 reads (8%) | called by muse, mutect2
- SAMD14 | c.823-117T>A | Intron (SNP) | VAF 15/386 reads (4%) | called by muse, mutect2
- SNORD116-28 | n.53G>T | RNA (SNP) | VAF 23/376 reads (6%) | called by muse, mutect2
- TGFBR3 | c.-312C>A | 5'UTR (SNP) | VAF 13/395 reads (3%) | called by muse, mutect2
- TIMM44 | c.1240-48G>T | Intron (SNP) | VAF 34/416 reads (8%) | called by muse, mutect2
